Surgical pathology report (de-identified scan), TCGA case TCGA-28-2513, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2513-01A (Primary Tumor).

CGA-28-2513

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. DURA BASED MASS (CRANIOTOMY):

- Meningioma, WHO grade I

B, I. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Glioblastoma multiforme, WHO grade IV
- (See comment)

C. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue with less than 5% of tumor necrosis on one piece

D. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue without tumor necrosis

E. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue without tumor necrosis

F. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue with approximately 20% tumor necrosis (5% on one piece and 15% on other piece)

G. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue without tumor necrosis

H. RIGHT TEMPORAL TUMOR (CRANIOTOMY):

- Cellular tumor tissue with 5% of tumor necrosis on one piece

COMMENT: Immunostain for MGMT is considered to be negative (10% tumor cells positive). There are approximately 50% of tumor cells to be positive for MAPK and PTEN. Laminin beta-1 is moderately elevated while laminin beta-2 is markedly elevated (see note).

Note:

A low percentage of tumor cells (20% and less) immunostaining for MGMT has been reported to be associated with a relative response to Temodar (). Hence, the 10% result in this case may suggest a likelihood of being responsive to Temodar.

Presence of activated (phosphorylated) p42/44 mitogen-activated protein kinase (pMAPK) in glioblastoma multiforme has been shown to be associated with a relative resistance to radiation therapy (). Hence, a high percentage of tumor cells immunoreactive to pMAPK antibody (although a cut-off point has not been well established yet at the moment) in this case may suggest the possibility of a relative resistance to radiation therapy.

Source: NCI Genomic Data Commons file f3167850-392c-4cb5-a32b-4d61bd6e3b3d (TCGA-28-2513.C7BA045F-48DD-42EA-8DA8-A5811B74E9FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).